Somatic mutation profile of tumor specimen 0DSMXY from CCDI case PBCHMW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 17.9 years (6,525 days).
Specimen 0DSMXY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12662d36-3aee-4223-b15c-4e88dbff6785.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSMYC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb2fae7a-541c-469e-a291-1de796a9d6b0

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Nonsense Mutation 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.159_173del p.F53_Q58delinsL | In Frame Del (DEL) | VAF 94/470 reads (20%) | catalogued as COSV61072289; called by mutect2, pindel, varscan2
- PPP1R3A | c.1078C>T p.Q360* | Nonsense Mutation (SNP) | VAF 19/580 reads (3%) | called by muse, mutect2
- CYHR1 | c.94-36T>C | Intron (SNP) | VAF 4/83 reads (5%) | called by muse, mutect2
